Somatic mutation profile of tumor specimen TCGA-DK-A1AD-01A (aliquot TCGA-DK-A1AD-01A-11D-A13W-08) from TCGA case TCGA-DK-A1AD, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 69.3 years (25,317 days).
Specimen TCGA-DK-A1AD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4467fdc-6ef7-4369-8df0-9cd6114142cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A1AD-10A (Blood Derived Normal), aliquot TCGA-DK-A1AD-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4bc8d11-2931-410a-b48c-b498ae99052b

The open-access MAF lists 268 somatic variants for this specimen: 198 protein-altering or splice-affecting, 62 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 172, Silent 62, Nonsense Mutation 12, Frame Shift Del 5, Splice Site 4, In Frame Del 3, RNA 3, Intron 3, 3'UTR 1, Frame Shift Ins 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTB | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs886041309, COSV59317066, COSV59317805; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 42/49 reads (86%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs587782705, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC3 | c.4012C>A p.R1338S | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53325061; called by muse, mutect2, varscan2
- ACADSB | c.344G>C p.G115A | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as COSV62551063; called by muse, mutect2, varscan2
- ADAM2 | c.1810C>G p.Q604E | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV55864799; called by muse, mutect2, varscan2
- ADAMTS14 | c.2645T>G p.M882R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV64603898; called by muse, mutect2, varscan2
- ADAMTS3 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs145300703; called by muse, mutect2, varscan2
- ADCY2 | c.562G>T p.V188F | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as COSV57883534; called by muse, mutect2, varscan2
- AMPD3 | c.4C>T p.P2S (on ENST00000396553 / NM_001025389.2; = p.P11S on NM_000480.3) | Missense Mutation (SNP) | VAF 93/228 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs867446911, COSV67330262; called by muse, mutect2, varscan2
- ANAPC1 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1435638489, COSV61977500; called by muse, mutect2, varscan2
- APLP1 | c.1711C>T p.L571= (on ENST00000221891 / NM_001024807.3; = p.L570= on NM_005166.4) | Splice Region (SNP) | VAF 53/77 reads (69%) | catalogued as COSV55705048; called by muse, mutect2, varscan2
- ARID1A | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 92/195 reads (47%) | catalogued as COSV61384529; called by muse, mutect2, varscan2
- ATAD2 | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 94/476 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54883461; called by muse, mutect2, varscan2
- ATG2B | c.5572C>T p.R1858* | Nonsense Mutation (SNP) | VAF 45/240 reads (19%) | catalogued as rs778403094, COSV55891447; called by muse, mutect2, varscan2
- ATP13A2 | c.3138G>C p.E1046D | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV58701841; called by muse, varscan2
- ATP6V0B | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 86/311 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs201522408, COSV52544080; called by muse, mutect2, varscan2
- AURKA | c.969A>C p.L323F | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57169137; called by muse, mutect2, varscan2
- B4GALT6 | c.967C>G p.H323D | Missense Mutation (SNP) | VAF 46/62 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV52704197; called by muse, mutect2, varscan2
- BMS1 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.257); catalogued as rs145513181, COSV100996826; called by muse, mutect2, varscan2
- BOD1L1 | c.6745G>C p.E2249Q | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV50025306; called by muse, mutect2, varscan2
- BRPF1 | c.2718G>T p.K906N | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.61); catalogued as COSV57406210; called by muse, mutect2, varscan2
- CASP8AP2 | c.5818G>C p.E1940Q | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52748338; called by muse, mutect2, varscan2
- CCDC114 | c.1676A>G p.H559R | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59557481; called by muse, mutect2, varscan2
- CCNB3 | c.173A>G p.K58R | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT tolerated (0.07); PolyPhen benign (0.333); catalogued as COSV52075957; called by muse, mutect2, varscan2
- CD1C | c.958G>T p.V320L | Missense Mutation (SNP) | VAF 90/1018 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.04); catalogued as COSV63806924; called by muse, mutect2
- CDC42BPA | c.4573G>C p.E1525Q (on ENST00000334218 / NM_001366019.2; = p.E1512Q on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.449); catalogued as COSV62014777, COSV62017206; called by muse, varscan2
- CDYL | c.1156G>A p.D386N (on ENST00000328908 / NM_001368125.1; = p.D332N on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV59360553; called by muse, mutect2, varscan2
- CEP112 | c.422C>G p.S141C | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV67142068; called by muse, mutect2, varscan2
- CFAP70 | c.2167G>C p.E723Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV60283042, COSV60284829; called by muse, mutect2, varscan2
- CHD7 | c.5898G>C p.W1966C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM126629, COSV71112547; called by muse, mutect2, varscan2
- CHN1 | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.024); catalogued as COSV55036298; called by muse, mutect2, varscan2
- CIITA | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV60859393; called by muse, mutect2, varscan2
- CLDN19 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs768727872; called by muse, mutect2
- CLOCK | c.392T>C p.I131T | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV59403416; called by muse, mutect2, varscan2
- COL19A1 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as COSV59593772; called by muse, mutect2
- COPZ2 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as COSV50058421, COSV99133599; called by muse, mutect2
- CPD | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 164/482 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373819167; called by muse, mutect2, varscan2
- CPED1 | c.1545G>A p.M515I | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs200776772, COSV60006707; called by muse, mutect2, varscan2
- CPNE8 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 20/275 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV58846669; called by muse, mutect2
- CRAT | c.523C>G p.Q175E | Missense Mutation (SNP) | VAF 110/336 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs761833732, COSV58877995; called by muse, varscan2
- CREBBP | c.4617T>G p.Y1539* | Nonsense Mutation (SNP) | VAF 84/152 reads (55%) | catalogued as COSV52128775; called by muse, varscan2
- CREBBP | c.2080G>C p.V694L | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.04); catalogued as COSV52131092; called by muse, mutect2, varscan2
- CXCL6 | c.217C>G p.P73A | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV56903162; called by muse, mutect2, varscan2
- DCAF12L1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs370562344, COSV64421438; called by muse, mutect2, varscan2
- DCAF6 | c.1487C>T p.T496I (on ENST00000312263 / NM_001349778.1; = p.T516I on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV56581260; called by muse, mutect2, varscan2
- DIS3L2 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV56058422; called by muse, mutect2, varscan2
- DMD | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 141/167 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1220963408, CM068398, COSV55884236; called by muse, mutect2, varscan2
- DSC1 | c.422C>A p.A141D | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs773770610, COSV57148047; called by muse, mutect2, varscan2
- ENDOD1 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.31); catalogued as COSV53590170; called by muse, mutect2, varscan2
- ENTPD3 | c.1060T>A p.S354T | Missense Mutation (SNP) | VAF 88/202 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV57195295; called by muse, mutect2, varscan2
- ESPL1 | c.2734C>G p.L912V | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57760744; called by muse, mutect2, varscan2
- EVC | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV53834795; called by muse, mutect2, varscan2
- FAM168B | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV66304340; called by muse, mutect2, varscan2
- FAM20B | c.464+1G>A p.X155_splice | Splice Site (SNP) | VAF 66/198 reads (33%) | catalogued as COSV55381151; called by muse, mutect2, varscan2
- FAM214A | c.1897A>G p.M633V | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1566926723, COSV55925568; called by muse, varscan2
- FAP | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 87/181 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs1459852729, COSV51864368; called by muse, mutect2, varscan2
- FAT4 | c.7616C>T p.S2539F | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs761295009, COSV58695516; called by muse, mutect2, varscan2
- FAT4 | c.13858G>T p.E4620* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | catalogued as COSV100628442; called by muse, mutect2, varscan2
- FBN1 | c.3768T>A p.N1256K | Missense Mutation (SNP) | VAF 63/134 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57322719; called by muse, mutect2, varscan2
- FBN3 | c.2296+1G>A p.X766_splice | Splice Site (SNP) | VAF 22/67 reads (33%) | catalogued as rs1468859412, COSV54465576; called by muse, mutect2, varscan2
- FLG | c.4475A>G p.H1492R | Missense Mutation (SNP) | VAF 139/1013 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV64244455; called by muse, mutect2, varscan2
- FOXP4 | c.204G>C p.Q68H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV57221411; called by muse, mutect2, varscan2
- FYCO1 | c.3079A>T p.S1027C | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as COSV56117498; called by muse, mutect2, varscan2
- FZD4 | c.358A>C p.M120L | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as COSV72294541; called by muse, mutect2, varscan2
- GAPDH | c.40A>G p.I14V | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV57521541; called by muse, mutect2, varscan2
- GLDC | c.1517G>C p.R506T | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs754119942, COSV58682230; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GNA13 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV71474980; called by muse, mutect2, varscan2
- GPR148 | c.817T>C p.Y273H | Missense Mutation (SNP) | VAF 79/163 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59308743; called by muse, mutect2, varscan2
- GPR68 | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.78); catalogued as COSV53176891; called by muse, mutect2, varscan2
- GRAMD2A | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59034281; called by muse, mutect2, varscan2
- H6PD | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs758495315, COSV66231461; called by muse, mutect2, varscan2
- HDGFL2 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56683796; called by muse, mutect2, varscan2
- HEATR1 | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.026); catalogued as COSV63979877, COSV63981993; called by muse, mutect2, varscan2
- HNRNPDL | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs1382181084, COSV55023041; called by muse, mutect2, varscan2
- HOMER1 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV56528099; called by muse, mutect2, varscan2
- HORMAD1 | c.974C>A p.S325Y | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV59272106; called by muse, mutect2, varscan2
- IFIH1 | c.951G>C p.Q317H | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV55124552; called by muse, mutect2, varscan2
- IFT74 | c.405-1G>A p.X135_splice | Splice Site (SNP) | VAF 73/227 reads (32%) | catalogued as COSV101197119, COSV66287715; called by muse, mutect2, varscan2
- INPP5F | c.1906A>G p.R636G | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV62822334; called by muse, mutect2, varscan2
- INSIG1 | c.538-2A>C p.X180_splice | Splice Site (SNP) | VAF 61/157 reads (39%) | catalogued as COSV60920728; called by muse, mutect2, varscan2
- IZUMO2 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as COSV53230636; called by muse, mutect2, varscan2
- KANSL3 | c.2297C>T p.S766F (on ENST00000666923 / NM_001349262.2; = p.S740F on NM_001115016.3) | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.424); catalogued as COSV62619263; called by muse, mutect2, varscan2
- KATNAL1 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 193/280 reads (69%) | catalogued as COSV66064170; called by muse, mutect2, varscan2
- KDM1A | c.866C>G p.S289* | Nonsense Mutation (SNP) | VAF 53/246 reads (22%) | catalogued as COSV100752619, COSV63089497; called by muse, mutect2, varscan2
- KHDRBS3 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV63421098; called by muse, varscan2
- KHDRBS3 | c.716G>T p.R239I | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV63414245, COSV63418241; called by muse, varscan2
- KIF14 | c.692G>C p.R231T | Missense Mutation (SNP) | VAF 395/464 reads (85%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV66262557; called by muse, mutect2, varscan2
- KIF21A | c.2329A>G p.M777V (on ENST00000361418 / NM_001378440.1; = p.M764V on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62774282; called by muse, mutect2, varscan2
- KIR2DL3 | c.797A>T p.H266L | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.197); catalogued as COSV60895826; called by muse, varscan2
- KLHL38 | c.1155C>G p.I385M | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58086775, COSV58088146; called by muse, mutect2, varscan2
- KLHL9 | c.263A>G p.Q88R | Missense Mutation (SNP) | VAF 80/374 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as COSV62922000; called by muse, mutect2, varscan2
- KMT2D | c.10657_10661del p.G3553* | Frame Shift Del (DEL) | VAF 36/89 reads (40%) | catalogued as COSV56459960; called by mutect2, pindel, varscan2
- LECT2 | c.327G>C p.K109N | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.346); catalogued as COSV50847397; called by muse, mutect2, varscan2
- LEPR | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs760392591, COSV60758057, COSV60758585; called by muse, mutect2, varscan2
- LGSN | c.704A>G p.H235R | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.219); catalogued as rs1290417656, COSV65727727; called by muse, mutect2, varscan2
- LRIT3 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59986200; called by muse, varscan2
- LRP1B | c.9171C>G p.I3057M | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV67246013; called by muse, mutect2, varscan2
- MACF1 | c.15971G>A p.R5324Q (on ENST00000372915; = p.R3257Q on NM_012090.5) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as rs148666575, COSV57133383; called by muse, mutect2, varscan2
- MACF1 | c.16229G>C p.R5410T (on ENST00000372915; = p.R3343T on NM_012090.5) | Missense Mutation (SNP) | VAF 15/84 reads (18%) | catalogued as COSV57130669, COSV57136185; called by muse, mutect2, varscan2
- MACROH2A1 | c.868C>G p.L290V (on ENST00000510038; = p.L289V on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV56896603; called by muse, mutect2, varscan2
- MCF2 | c.2329G>C p.E777Q | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58489023; called by muse, mutect2, varscan2
- MCM8 | c.320T>G p.I107S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV52544453; called by muse, mutect2, varscan2
- MDC1 | c.4685G>A p.R1562K | Missense Mutation (SNP) | VAF 148/260 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV64523762, COSV64525486, COSV64527108; called by muse, varscan2
- MEGF8 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.179); catalogued as COSV52092144; called by muse, mutect2, varscan2
- MGA | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 141/416 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54957769; called by muse, mutect2, varscan2
- MRPL35 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs201070030, COSV54493377; called by muse, mutect2, varscan2
- MYH13 | c.5659G>A p.E1887K | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52834764; called by muse, mutect2, varscan2
- MYO3A | c.1544G>T p.R515L | Missense Mutation (SNP) | VAF 75/126 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200209381, COSV56330720, COSV56338173; called by muse, mutect2, varscan2
- MYORG | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as COSV52627667; called by muse, mutect2, varscan2
- NCAM1 | c.1326del p.S443Vfs*34 (on ENST00000316851 / NM_181351.5; = p.S433Vfs*34 on NM_000615.7) | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as COSV57513191; called by mutect2, pindel, varscan2
- NCAM2 | c.255A>G p.I85M | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); catalogued as COSV53086975; called by muse, mutect2, varscan2
- NCKAP5 | c.3462G>C p.M1154I | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs776322064, COSV58457469; called by muse, mutect2, varscan2
- NCSTN | c.1906G>C p.E636Q | Missense Mutation (SNP) | VAF 36/453 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.47); catalogued as COSV54189129; called by muse, mutect2
- NEXMIF | c.1710G>C p.L570F | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50050351; called by muse, mutect2, varscan2
- NRDC | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated, low confidence (0.37); PolyPhen probably damaging (0.956); catalogued as rs758222716, COSV61406111; called by muse, mutect2, varscan2
- NYAP1 | c.1786G>T p.D596Y | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs557553256, COSV55717115, COSV55720148; called by muse, mutect2, varscan2
- OR1C1 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 41/48 reads (85%) | SIFT tolerated (0.36); PolyPhen benign (0.357); catalogued as COSV68715860; called by muse, mutect2, varscan2
- OR5R1 | c.445T>C p.Y149H | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as COSV56572896; called by muse, mutect2, varscan2
- OR6Q1 | c.826A>C p.K276Q | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV56933708; called by muse, mutect2, varscan2
- OR9Q1 | c.359A>G p.Y120C | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as rs1329637201, COSV59042888; called by muse, mutect2
- OVCH1 | c.1163C>A p.A388D | Missense Mutation (SNP) | VAF 69/123 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs1256434150, COSV58963490, COSV58965279; called by muse, mutect2, varscan2
- P2RX6 | c.854A>G p.Y285C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60384811; called by muse, mutect2, varscan2
- P2RY1 | c.536T>C p.V179A | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV59309853; called by muse, mutect2, varscan2
- PABPC5 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57041822; called by muse, mutect2, varscan2
- PABPC5 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57041210; called by muse, mutect2, varscan2
- PDGFRB | c.1781A>G p.E594G | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55807335; called by muse, mutect2, varscan2
- PDHA2 | c.76C>A p.R26S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.106); catalogued as COSV54779955, COSV54780252; called by muse, mutect2, varscan2
- PDZRN4 | c.2905G>A p.E969K (on ENST00000402685 / NM_001164595.2; = p.E711K on NM_013377.4) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV54207669; called by muse, mutect2, varscan2
- PIP5K1A | c.573C>G p.F191L (on ENST00000368888 / NM_001135638.2; = p.F178L on NM_003557.3) | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as COSV62959086; called by muse, varscan2
- PKDREJ | c.3364G>A p.G1122S | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53548795; called by muse, mutect2, varscan2
- PLP2 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.762); catalogued as rs781844616, COSV66240181; called by muse, mutect2, varscan2
- PNOC | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as COSV57284002; called by muse, mutect2, varscan2
- PPM1B | c.715A>G p.I239V | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56768011; called by muse, mutect2, varscan2
- PSG7 | c.142G>C p.G48R | Missense Mutation (SNP) | VAF 66/425 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV68445767; called by muse, mutect2, varscan2
- PTPRD | c.1191T>A p.N397K | Missense Mutation (SNP) | VAF 61/256 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61961244; called by muse, mutect2, varscan2
- RACGAP1 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56699972; called by muse, mutect2, varscan2
- RAD21 | c.1745T>C p.L582P | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); catalogued as COSV52060972; called by muse, mutect2, varscan2
- RAD21 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV52060985; called by muse, mutect2, varscan2
- RASL10A | c.243G>C p.W81C | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.935); catalogued as COSV53330954; called by muse, mutect2, varscan2
- RBM39 | c.1278C>G p.F426L (on ENST00000253363 / NM_001323424.2; = p.F420L on NM_004902.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV53616220; called by muse, mutect2, varscan2
- RBM47 | c.1410C>G p.I470M (on ENST00000295971 / NM_001098634.2; = p.I401M on NM_019027.4) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.022); catalogued as COSV55938017; called by muse, mutect2, varscan2
- RGMB | c.487dup p.C163Lfs*15 (on ENST00000513185 / NM_001366508.1; = p.C204Lfs*15 on NM_001012761.3 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 6/25 reads (24%) | catalogued as rs1195825738; called by pindel, varscan2
- RGS18 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV66508947; called by muse, mutect2, varscan2
- RIMKLB | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 53/90 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV55238495; called by muse, mutect2, varscan2
- S1PR4 | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1435957430, COSV55739583; called by muse, mutect2, varscan2
- SAMD15 | c.1543G>C p.D515H | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV53626989; called by muse, mutect2, varscan2
- SCAF4 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 65/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54589319; called by muse, mutect2, varscan2
- SCAPER | c.3275G>A p.G1092D | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.088); catalogued as COSV57745083; called by muse, mutect2, varscan2
- SEMA3D | c.891A>G p.I297M | Missense Mutation (SNP) | VAF 210/552 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52397990; called by muse, mutect2, varscan2
- SH3PXD2B | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs138949033; called by muse, mutect2, varscan2
- SLC10A2 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV55361250; called by muse, mutect2
- SLC18A3 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as rs200894047, COSV60328304; called by muse, mutect2, varscan2
- SLC19A1 | c.1226T>C p.I409T | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV60755823; called by muse, mutect2, varscan2
- SLC4A5 | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1276164475, COSV61030013; called by muse, mutect2, varscan2
- SMC2 | c.3006G>C p.M1002I | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as COSV53960699; called by muse, mutect2, varscan2
- SSTR4 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs563306096, COSV54798920; called by muse, mutect2, varscan2
- STAT1 | c.1531A>G p.K511E | Missense Mutation (SNP) | VAF 104/226 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.106); catalogued as COSV63116790; called by muse, mutect2, varscan2
- STC2 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs372362093, COSV54180853; called by muse, mutect2, varscan2
- SYNPO2 | c.2856G>C p.K952N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV61113793, COSV61118081; called by muse, mutect2, varscan2
- SYT5 | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.308); catalogued as COSV54747376; called by muse, mutect2, varscan2
- TAS2R50 | c.871C>G p.L291V | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as COSV101114716, COSV67858437; called by muse, mutect2, varscan2
- TEX15 | c.4238C>A p.A1413E (on ENST00000256246; = p.A1796E on NM_001350162.2) | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV56349342; called by muse, mutect2, varscan2
- TGM4 | c.1002G>A p.M334I | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56095000; called by muse, mutect2, varscan2
- TOGARAM1 | c.920A>G p.Y307C | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV61888718; called by muse, mutect2, varscan2
- TRIM27 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as rs112674133, COSV65873745; called by muse, mutect2, varscan2
- TRPC6 | c.746A>G p.H249R | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60257483; called by muse, mutect2, varscan2
- TRPM6 | c.4315C>T p.P1439S | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as rs144291419; called by muse, mutect2, varscan2
- TTN | c.89267C>T p.S29756L (on ENST00000591111; = p.S22332L on NM_003319.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | PolyPhen possibly damaging (0.843); catalogued as COSV60176574; called by muse, mutect2, varscan2
- TYW5 | c.635C>G p.S212C | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.329); catalogued as COSV63562611; called by muse, mutect2, varscan2
- U2SURP | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.46); catalogued as COSV67532005; called by muse, mutect2, varscan2
- UBQLN4 | c.1468C>G p.L490V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV64149772; called by mutect2, varscan2
- ULK4 | c.1937G>A p.G646E | Missense Mutation (SNP) | VAF 115/303 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as rs1461982511, COSV57214175; called by muse, mutect2, varscan2
- UNC5D | c.1658G>T p.G553V | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54810326; called by muse, mutect2, varscan2
- USF3 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 9/233 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as COSV57074833; called by muse, mutect2
- ZBED4 | c.2861T>A p.L954H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53466653; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1460G>C p.R487T | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV56273467, COSV56273593; called by muse, mutect2, varscan2
- ZNF197 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 14/421 reads (3%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.824); catalogued as COSV60361035; called by muse, mutect2
- ZNF236 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.67); catalogued as rs774794079, COSV53485175; called by muse, mutect2, varscan2
- ZNF236 | c.2202C>G p.I734M | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.678); catalogued as COSV53491796; called by muse, mutect2, varscan2
- ZNF626 | c.744G>C p.K248N | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV101657004, COSV74129340; called by muse, mutect2, varscan2
- ZSWIM4 | c.1979C>T p.A660V | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV54323766; called by muse, mutect2, varscan2
- AGO2 | c.2056del p.A686Pfs*9 | Frame Shift Del (DEL) | VAF 21/120 reads (18%) | called by mutect2, pindel, varscan2
- ANKRD20A1 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 74/196 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0); called by mutect2, varscan2
- CASP8AP2 | c.1324A>G p.T442A | Missense Mutation (SNP) | VAF 98/179 reads (55%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC50 | c.18C>G p.I6M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- CFAP47 | c.434C>G p.S145* | Nonsense Mutation (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2, varscan2
- CLDN5 | c.87G>T p.M29I (on ENST00000618236 / NM_001363066.2; = p.M114I on NM_003277.4) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2
- EXT1 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 253/476 reads (53%) | called by muse, mutect2, varscan2
- FANCM | c.1202del p.N401Mfs*10 | Frame Shift Del (DEL) | VAF 29/76 reads (38%) | called by mutect2, pindel, varscan2
- MAP4K4 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- NKTR | c.1717C>T p.Q573* | Nonsense Mutation (SNP) | VAF 54/246 reads (22%) | called by muse, mutect2, varscan2
- NXF1 | c.1777_1779del p.N593del | In Frame Del (DEL) | VAF 20/79 reads (25%) | called by pindel, varscan2
- PCSK5 | c.1732C>T p.Q578* | Nonsense Mutation (SNP) | VAF 53/149 reads (36%) | called by muse, mutect2, varscan2
- POM121 | c.1451_1452del p.T484Nfs*21 (on ENST00000434423; = p.T219Nfs*21 on NM_172020.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 118/439 reads (27%) | called by mutect2, pindel, varscan2
- SBF2 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- TDRD3 | c.224C>G p.S75* | Nonsense Mutation (SNP) | VAF 49/188 reads (26%) | called by muse, mutect2, varscan2
- UBLCP1 | c.613_615del p.Y205del | In Frame Del (DEL) | VAF 21/77 reads (27%) | called by mutect2, pindel, varscan2
- UFSP2 | c.1055_1063del p.G352_I354del | In Frame Del (DEL) | VAF 4/49 reads (8%) | called by pindel, varscan2*
- ANXA5 | c.789G>A p.G263= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs750613571, COSV56639476; called by muse, mutect2, varscan2
- ARMC9 | c.1695C>T p.F565= | Silent (SNP) | VAF 48/142 reads (34%) | catalogued as COSV63022188; called by muse, mutect2, varscan2
- BARHL2 | c.489C>T p.S163= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV64981597; called by muse, mutect2, varscan2
- BRCA2 | c.7389T>C p.N2463= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV66457303; called by muse, mutect2, varscan2
- C11orf16 | c.927G>A p.L309= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV58168248; called by muse, mutect2
- C9orf131 | c.2367C>G p.L789= | Silent (SNP) | VAF 107/287 reads (37%) | catalogued as COSV56612384; called by muse, mutect2, varscan2
- CA7 | c.177C>T p.L59= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as rs756567978, COSV58156851; called by muse, mutect2, varscan2
- CBX6 | c.423G>A p.G141= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs768447845, COSV99328163; called by muse, varscan2
- CPS1 | c.3843G>A p.K1281= | Silent (SNP) | VAF 95/323 reads (29%) | catalogued as COSV51816024, COSV99243041; called by muse, mutect2, varscan2
- DEFB125 | c.297G>C p.L99= | Silent (SNP) | VAF 176/308 reads (57%) | catalogued as COSV66703434; called by muse, mutect2, varscan2
- DIP2B | c.2001C>A p.I667= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV56587299; called by muse, mutect2, varscan2
- DNTTIP2 | c.99G>A p.A33= | Silent (SNP) | VAF 38/66 reads (58%) | catalogued as rs777286707, COSV63284317; called by muse, mutect2, varscan2
- DYM | c.411T>C p.P137= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV53988127; called by muse, mutect2, varscan2
- ERBB4 | c.1926C>T p.S642= | Silent (SNP) | VAF 50/112 reads (45%) | catalogued as COSV53552758; called by muse, mutect2, varscan2
- FAM47A | c.307C>T p.L103= | Silent (SNP) | VAF 99/112 reads (88%) | catalogued as COSV60498182; called by muse, mutect2, varscan2
- FAM71F1 | c.150G>T p.A50= | Silent (SNP) | VAF 64/153 reads (42%) | catalogued as COSV100170822, COSV59374233; called by muse, mutect2, varscan2
- H1-5 | c.330C>G p.L110= | Silent (SNP) | VAF 52/255 reads (20%) | catalogued as rs970755186, COSV58900658; called by muse, mutect2, varscan2
- H2AJ | c.168G>A p.L56= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV63762260; called by muse, mutect2, varscan2
- HERC2 | c.2604G>T p.T868= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs139718674, COSV55334321; called by muse, mutect2, varscan2
- HSPG2 | c.7368G>C p.L2456= | Silent (SNP) | VAF 40/134 reads (30%) | catalogued as COSV65973903; called by muse, mutect2, varscan2
- IPO8 | c.711C>T p.I237= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV56240872; called by muse, mutect2, varscan2
- IRGQ | c.57G>A p.G19= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV60671005; called by muse, mutect2, varscan2
- KAT8 | c.1077C>T p.L359= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV54897710; called by muse, mutect2, varscan2
- KCNU1 | c.420T>C p.P140= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as COSV67757733; called by muse, mutect2, varscan2
- KDM1B | c.1941G>A p.K647= (on ENST00000449850; = p.K414= on NM_153042.4) | Silent (SNP) | VAF 120/867 reads (14%) | catalogued as COSV52810639, COSV52812509; called by muse, mutect2, varscan2
- KRTAP6-3 | c.186C>T p.G62= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV66963120, COSV66963135; called by muse, mutect2, varscan2
- LRRC4 | c.91C>T p.L31= | Silent (SNP) | VAF 66/157 reads (42%) | catalogued as COSV50815446, COSV50815960; called by muse, mutect2, varscan2
- LRRC8D | c.1842A>G p.T614= | Silent (SNP) | VAF 50/159 reads (31%) | catalogued as COSV61577841; called by muse, mutect2, varscan2
- MAP11 | c.1377G>C p.L459= | Silent (SNP) | VAF 89/225 reads (40%) | catalogued as COSV57586996; called by muse, mutect2, varscan2
- MROH1 | c.1491C>T p.F497= | Silent (SNP) | VAF 38/62 reads (61%) | called by muse, varscan2
- MSS51 | c.1251C>G p.L417= | Silent (SNP) | VAF 53/128 reads (41%) | catalogued as rs1226418655, COSV55019737; called by muse, mutect2, varscan2
- MYOM3 | c.3522C>T p.L1174= | Silent (SNP) | VAF 58/208 reads (28%) | catalogued as COSV58396729; called by muse, mutect2, varscan2
- NECTIN2 | c.759G>A p.V253= | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as rs779726567, COSV52978451; called by muse, mutect2, varscan2
- OR4C11 | c.228C>A p.A76= | Silent (SNP) | VAF 73/144 reads (51%) | catalogued as COSV56354110; called by muse, mutect2, varscan2
- PCDHB2 | c.2235G>A p.G745= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as COSV99165483; called by muse, mutect2, varscan2
- PCDHB8 | c.2286G>A p.T762= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as rs371278694; called by muse, mutect2, varscan2
- PDE4DIP | c.1347G>A p.L449= | Silent (SNP) | VAF 116/201 reads (58%) | catalogued as rs1553517656, COSV57708566; called by mutect2, varscan2
- PKDCC | c.1302C>T p.L434= | Silent (SNP) | VAF 42/175 reads (24%) | catalogued as rs1477091490, COSV54307517; called by muse, mutect2, varscan2
- PLOD2 | c.963G>A p.L321= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV51466540; called by muse, mutect2, varscan2
- PTCH1 | c.2772G>T p.T924= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs1554691694, COSV59482847; ClinVar: likely benign; called by muse, mutect2, varscan2
- RPLP1 | c.93C>T p.L31= | Silent (SNP) | VAF 77/155 reads (50%) | catalogued as COSV53006676, COSV53006702; called by muse, mutect2, varscan2
- SCRIB | c.745C>T p.L249= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1335407642, COSV57589841; called by muse, mutect2, varscan2
- SEC62 | c.681C>T p.L227= | Silent (SNP) | VAF 62/299 reads (21%) | catalogued as COSV61261679; called by muse, mutect2, varscan2
- SH3PXD2A | c.3318T>C p.N1106= (on ENST00000369774 / NM_001365079.1; = p.N1078= on NM_014631.2) | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs769703680, COSV60118522; called by muse, mutect2, varscan2
- SLC45A2 | c.678C>T p.L226= | Silent (SNP) | VAF 21/132 reads (16%) | catalogued as rs1387107095, COSV56873321; called by muse, mutect2, varscan2
- SLC47A1 | c.1584G>A p.P528= | Silent (SNP) | VAF 42/211 reads (20%) | catalogued as rs1332048741, COSV54502403; called by muse, mutect2, varscan2
- SMPD3 | c.1224C>T p.L408= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs959432863, COSV54713710; called by mutect2, varscan2
- SPATA31A1 | c.210G>A p.R70= | Silent (SNP) | VAF 28/103 reads (27%) | called by mutect2, varscan2
- STX11 | c.561C>T p.D187= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV62449555; called by muse, mutect2, varscan2
- TJP2 | c.1500T>G p.P500= | Silent (SNP) | VAF 73/137 reads (53%) | catalogued as COSV55269667; called by muse, mutect2, varscan2
- TLN1 | c.7560G>A p.K2520= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV59209299; called by muse, mutect2, varscan2
- TMEM171 | c.357C>T p.F119= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as COSV55131007; called by muse, mutect2, varscan2
- TP53AIP1 | c.93C>T p.L31= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV71688814; called by muse, mutect2, varscan2
- TPH2 | c.993G>A p.K331= | Silent (SNP) | VAF 36/179 reads (20%) | catalogued as rs754918661, COSV61592901; called by muse, mutect2, varscan2
- TRHR | c.657C>T p.F219= | Silent (SNP) | VAF 37/164 reads (23%) | catalogued as rs1473134618, COSV61235273; called by muse, mutect2, varscan2
- TRIM36 | c.1572T>C p.N524= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as COSV56691415; called by muse, mutect2, varscan2
- UTRN | c.4650G>A p.K1550= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV62329229, COSV62340508; called by muse, mutect2, varscan2
- WASHC5 | c.2343C>T p.N781= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as rs1164371151, COSV59198214; called by muse, mutect2, varscan2
- ZGLP1 | c.411C>T p.T137= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as rs878999327, COSV100593772; called by muse, mutect2
- ZGPAT | c.327G>A p.A109= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs1481462194, COSV60832736; called by muse, mutect2, varscan2
- ZHX1 | c.1059G>A p.R353= | Silent (SNP) | VAF 295/552 reads (53%) | catalogued as COSV52877251; called by muse, mutect2, varscan2
- ZNF700 | c.702C>T p.F234= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as COSV54313986; called by muse, mutect2, varscan2
- CACNA1G | c.4422+103G>A | Intron (SNP) | VAF 13/80 reads (16%) | catalogued as rs1018471376, COSV61731733; called by muse, mutect2, varscan2
- GLRXP3 | n.244G>A | RNA (SNP) | VAF 50/137 reads (36%) | catalogued as rs532965981; called by muse, mutect2, varscan2
- L1CAM | chrX:153888567 G>A | 5'Flank (SNP) | VAF 16/20 reads (80%) | catalogued as rs782216855; called by muse, mutect2, varscan2
- PKD1L2 | n.664C>T | RNA (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
- SNX18 | c.*60G>A | 3'UTR (SNP) | VAF 31/100 reads (31%) | catalogued as COSV57990596; called by muse, mutect2, varscan2
- THSD4 | c.1016-70439C>G | Intron (SNP) | VAF 24/101 reads (24%) | called by muse, mutect2, varscan2
- VSTM4 | c.457+3769C>A | Intron (SNP) | VAF 16/50 reads (32%) | catalogued as COSV53677728; called by muse, mutect2, varscan2
- ZNF322P1 | n.1061C>T | RNA (SNP) | VAF 76/289 reads (26%) | called by muse, mutect2, varscan2
